MMRF case MMRF_1031 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/23d14752-5484-4b51-9897-f91a8ac333a4

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 62 years; Vital status: Dead; Days to death: 1,670 days (4.6 years); Cause of death: Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 62.3 years (22,760 days); ISS stage: I; Days to last known disease status: 1,670 days (4.6 years); Days to last follow up: 1,670 days (4.6 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 61 days.
   Treatment given: Therapeutic agents: Other; Regimen or line of therapy: First line of therapy; Days to treatment start: 185 days; Days to treatment end: 1,339 days (3.7 years).
   Treatment given: Therapeutic agents: Dexamethasone + Lenalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 1,339 days (3.7 years); Days to treatment end: 1,581 days (4.3 years).
   Treatment given: Therapeutic agents: Carfilzomib + Dexamethasone; Regimen or line of therapy: Third line of therapy; Days to treatment start: 1,581 days (4.3 years); Days to treatment end: 1,670 days (4.6 years).

Follow-up (1 entry)
- Follow-up contact recording only the day: day 1,670.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -1 (ECOG 0): M Protein 1.52 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 23.6 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.17 mg/dL; Immunoglobulin G 6.47 g/L; Immunoglobulin A 15.2 g/L; Immunoglobulin M 0.76 g/L; Beta 2 Microglobulin 2.04 µg/mL; Lactate Dehydrogenase 2.8 µkat/L; Hemoglobin 6.32 mmol/L; Leukocytes 12.4 ×10⁹/L; Absolute Neutrophil 10.3 ×10⁹/L; Platelets 385 ×10⁹/L; Creatinine 81.3 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.45 mmol/L; Albumin 35 g/L; Total Protein 7.9 g/dL; Glucose 11 mmol/L; C-Reactive Protein 6.78 mg/dL.
- Day 104 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.16 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.711 mg/dL; Immunoglobulin G 4.27 g/L; Immunoglobulin A 0.23 g/L; Immunoglobulin M 0.33 g/L; Beta 2 Microglobulin 2.18 µg/mL; Lactate Dehydrogenase 4.12 µkat/L; Hemoglobin 7.87 mmol/L; Leukocytes 9.7 ×10⁹/L; Absolute Neutrophil 6.4 ×10⁹/L; Platelets 166 ×10⁹/L; Creatinine 78.7 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.48 mmol/L; Albumin 45 g/L; Total Protein 6.7 g/dL; Glucose 5.5 mmol/L.
- Day 183 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.92 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.831 mg/dL; Immunoglobulin G 6.23 g/L; Immunoglobulin A 0.33 g/L; Immunoglobulin M 0.48 g/L; Beta 2 Microglobulin 1.99 µg/mL; Lactate Dehydrogenase 3.03 µkat/L; Hemoglobin 7.81 mmol/L; Leukocytes 7.4 ×10⁹/L; Absolute Neutrophil 4.1 ×10⁹/L; Platelets 162 ×10⁹/L; Creatinine 76.9 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.4 mmol/L; Albumin 46 g/L; Total Protein 6.7 g/dL; Glucose 6.27 mmol/L.
- Day 281 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.27 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.12 mg/dL; Immunoglobulin G 9.49 g/L; Immunoglobulin A 0.44 g/L; Immunoglobulin M 1.12 g/L; Beta 2 Microglobulin 1.97 µg/mL; Lactate Dehydrogenase 3.78 µkat/L; Hemoglobin 7.13 mmol/L; Leukocytes 8.7 ×10⁹/L; Absolute Neutrophil 3.9 ×10⁹/L; Platelets 147 ×10⁹/L; Creatinine 87.5 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.35 mmol/L; Albumin 40 g/L; Total Protein 6.6 g/dL; Glucose 5.61 mmol/L.
- Day 328 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.06 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.872 mg/dL; Immunoglobulin G 7.32 g/L; Immunoglobulin A 0.27 g/L; Immunoglobulin M 0.42 g/L; Beta 2 Microglobulin 2.22 µg/mL; Hemoglobin 6.94 mmol/L; Leukocytes 7.2 ×10⁹/L; Absolute Neutrophil 3.3 ×10⁹/L; Platelets 166 ×10⁹/L; Creatinine 78.7 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.3 mmol/L; Albumin 40 g/L; Total Protein 6.2 g/dL; Glucose 7.43 mmol/L.
- Day 426 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.973 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.153 mg/dL; Immunoglobulin G 4.76 g/L; Immunoglobulin A 0.17 g/L; Immunoglobulin M 0.23 g/L; Lactate Dehydrogenase 2.85 µkat/L; Hemoglobin 9.49 mmol/L; Leukocytes 4 ×10⁹/L; Absolute Neutrophil 2.1 ×10⁹/L; Platelets 94 ×10⁹/L; Creatinine 84 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.2 mmol/L; Albumin 42 g/L; Total Protein 6.5 g/dL; Glucose 6.55 mmol/L.
- Day 519 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.11 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.43 mg/dL; Immunoglobulin G 8.62 g/L; Immunoglobulin A 0.85 g/L; Immunoglobulin M 0.37 g/L; Beta 2 Microglobulin 2.11 µg/mL; Hemoglobin 7.81 mmol/L; Leukocytes 6.1 ×10⁹/L; Absolute Neutrophil 3.4 ×10⁹/L; Platelets 182 ×10⁹/L; Creatinine 75.1 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 2.28 mmol/L; Albumin 36 g/L; Total Protein 6.5 g/dL; Glucose 5.67 mmol/L.
- Day 615 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.39 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.74 mg/dL; Immunoglobulin G 8.49 g/L; Immunoglobulin A 0.49 g/L; Immunoglobulin M 0.35 g/L; Lactate Dehydrogenase 2.83 µkat/L; Hemoglobin 9.18 mmol/L; Leukocytes 6.4 ×10⁹/L; Absolute Neutrophil 3.7 ×10⁹/L; Platelets 160 ×10⁹/L; Creatinine 91.1 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.35 mmol/L; Albumin 46 g/L; Total Protein 7 g/dL; Glucose 6.38 mmol/L.
- Day 755 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.757 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.636 mg/dL; Immunoglobulin G 6.03 g/L; Immunoglobulin A 0.4 g/L; Immunoglobulin M 0.4 g/L; Hemoglobin 8.87 mmol/L; Leukocytes 10.4 ×10⁹/L; Absolute Neutrophil 7.4 ×10⁹/L; Platelets 151 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.45 mmol/L; Albumin 45 g/L; Total Protein 6.9 g/dL; Glucose 5.39 mmol/L.
- Day 846 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.09 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.659 mg/dL; Immunoglobulin G 6.19 g/L; Immunoglobulin A 0.46 g/L; Immunoglobulin M 0.33 g/L; Hemoglobin 8.56 mmol/L; Leukocytes 9.7 ×10⁹/L; Absolute Neutrophil 6.6 ×10⁹/L; Platelets 146 ×10⁹/L; Creatinine 80.4 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.48 mmol/L; Albumin 43 g/L; Total Protein 7 g/dL; Glucose 5.78 mmol/L.
- Day 1,000 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.828 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.632 mg/dL; Immunoglobulin G 7.51 g/L; Immunoglobulin A 0.49 g/L; Immunoglobulin M 0.41 g/L; Hemoglobin 8.93 mmol/L; Leukocytes 7.8 ×10⁹/L; Absolute Neutrophil 4.9 ×10⁹/L; Platelets 150 ×10⁹/L; Creatinine 89.3 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.43 mmol/L; Albumin 44 g/L; Total Protein 7 g/dL; Glucose 8.36 mmol/L.
- Day 1,094 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.16 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.711 mg/dL; Immunoglobulin G 6.2 g/L; Immunoglobulin A 0.52 g/L; Immunoglobulin M 0.43 g/L; Hemoglobin 8.62 mmol/L; Leukocytes 10.3 ×10⁹/L; Absolute Neutrophil 6.4 ×10⁹/L; Platelets 153 ×10⁹/L; Creatinine 84.9 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.63 mmol/L; Albumin 46 g/L; Total Protein 7 g/dL; Glucose 5.61 mmol/L.
- Day 1,329 (ECOG 1): M Protein 0.71 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.41 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.533 mg/dL; Immunoglobulin G 5.86 g/L; Immunoglobulin A 7.14 g/L; Immunoglobulin M 0.41 g/L; Hemoglobin 8.31 mmol/L; Leukocytes 14 ×10⁹/L; Absolute Neutrophil 9.94 ×10⁹/L; Platelets 243 ×10⁹/L; Creatinine 95.5 µmol/L; Blood Urea Nitrogen 9.28 mmol/L; Calcium 2.43 mmol/L; Albumin 43 g/L; Total Protein 7.5 g/dL; Glucose 16.2 mmol/L.
- Day 1,392 (ECOG 1): M Protein 0.18 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.55 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.8 mg/dL; Immunoglobulin G 7.4 g/L; Immunoglobulin A 0.93 g/L; Immunoglobulin M 0.81 g/L; Beta 2 Microglobulin 2.51 µg/mL; Lactate Dehydrogenase 4.13 µkat/L; Hemoglobin 6.63 mmol/L; Leukocytes 4.5 ×10⁹/L; Absolute Neutrophil 2.79 ×10⁹/L; Platelets 175 ×10⁹/L; Creatinine 69 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.2 mmol/L; Albumin 31 g/L; Total Protein 5.8 g/dL; Glucose 6.11 mmol/L.
- Day 1,437 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.34 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.829 mg/dL; Immunoglobulin G 4.66 g/L; Immunoglobulin A 0.53 g/L; Immunoglobulin M 0.32 g/L; Lactate Dehydrogenase 3.48 µkat/L; Hemoglobin 7.63 mmol/L; Leukocytes 11.8 ×10⁹/L; Absolute Neutrophil 8.4 ×10⁹/L; Platelets 125 ×10⁹/L; Creatinine 86.6 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.43 mmol/L; Albumin 38 g/L; Total Protein 6.1 g/dL; Glucose 9.52 mmol/L.
- Day 1,581 (ECOG 1): M Protein 1.25 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 7.32 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.318 mg/dL; Immunoglobulin G 3.39 g/L; Immunoglobulin A 17.5 g/L; Immunoglobulin M 0.25 g/L; Lactate Dehydrogenase 5.65 µkat/L; Hemoglobin 6.88 mmol/L; Leukocytes 14.4 ×10⁹/L; Absolute Neutrophil 12.5 ×10⁹/L; Platelets 127 ×10⁹/L; Creatinine 133 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.43 mmol/L; Albumin 38 g/L; Total Protein 7.9 g/dL; Glucose 6.55 mmol/L.

Other clinical attributes
- Day -1: Weight: 83 kg; Height: 155 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_1031_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -1 day.
- Sample MMRF_1031_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -1 day.
